Somatic mutation profile of tumor specimen 0DRY7Z from CCDI case PBCHJR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.3 years (1,572 days).
Specimen 0DRY7Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00cd99d6-42ee-40ce-8846-6828f96b9f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY8B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc62f09b-8e03-4abf-a623-725c9b83a5f7

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 443/865 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIF26A | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747086678; called by muse, mutect2, varscan2
- SLC9A1 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 228/281 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.402); catalogued as rs368322522; called by muse, mutect2, varscan2
- TCF4 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 285/634 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61890504, COSV61895378, COSV61897744; called by muse, mutect2, varscan2
- TMCO5A | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 316/703 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs373271370, COSV60465985; called by muse, mutect2, varscan2
- ZNF322 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 166/623 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1393937856; called by muse, mutect2, varscan2
- FTHL18 | n.390C>T | RNA (SNP) | VAF 106/113 reads (94%) | catalogued as rs1236286612; called by muse, mutect2, varscan2
